CCDI case PBBTLN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5bb7527f-f561-4e9b-b76d-a5b604b3e139

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 5.8 years (2,107 days).

Biospecimens (4 samples)
- Samples 0DGMHG, 0DGMHP (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGMI0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGRHD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
